Somatic mutation profile of tumor specimen C3N-02575-01 (aliquot CPT0147680010) from CPTAC case C3N-02575, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 70.0 years (25,569 days).
Specimen C3N-02575-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad65fc41-c4ca-42e5-8230-c157c4db3d73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02575-71 (Blood Derived Normal), aliquot CPT0147710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/312f69ca-acb5-412b-86a9-cff910770b8f

The open-access MAF lists 366 somatic variants for this specimen: 251 protein-altering or splice-affecting, 77 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 77, Nonsense Mutation 20, Intron 19, Frame Shift Del 12, RNA 9, Splice Site 5, 3'UTR 4, Splice Region 4, Frame Shift Ins 3, 5'UTR 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.5434G>T p.E1812* | Nonsense Mutation (SNP) | VAF 85/182 reads (47%) | catalogued as rs80358767, CM120143, COSV66452283; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CUBN | c.10285dup p.Q3429Pfs*19 | Frame Shift Ins (INS) | VAF 223/384 reads (58%) | catalogued as rs754704005; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 402/635 reads (63%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI3 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 202/275 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as rs769714351, COSV56799151; called by muse, mutect2, varscan2
- ACSM2A | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs1314527864; called by muse, mutect2, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 166/499 reads (33%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel, varscan2
- AFF3 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57851215; called by muse, varscan2
- ARID1A | c.3848G>A p.G1283D | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as rs1461233133; called by muse, mutect2, varscan2
- BID | c.568_570del p.K190del (on ENST00000317361 / NM_197966.2; = p.K144del on NM_001196.4) | In Frame Del (DEL) | VAF 93/541 reads (17%) | catalogued as rs762626576; called by mutect2, pindel, varscan2
- BRINP1 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 157/454 reads (35%) | catalogued as COSV56301734, COSV99774824; called by muse, mutect2, varscan2
- C22orf34 | n.101G>T | Splice Region (SNP) | VAF 66/256 reads (26%) | catalogued as rs1398931552; called by muse, varscan2
- CACNA1A | c.2809G>T p.V937L | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV64190238; called by muse, mutect2, varscan2
- CALN1 | c.149G>T p.R50L (on ENST00000329008 / NM_001017440.3; = p.R92L on NM_031468.4) | Missense Mutation (SNP) | VAF 125/422 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV61118039, COSV61119958; called by muse, mutect2, varscan2
- CDH10 | c.2312G>C p.R771P | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV52592676; called by muse, mutect2, varscan2
- CDH9 | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.019); catalogued as rs1202948043; called by muse, mutect2, varscan2
- CEP250 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 96/191 reads (50%) | catalogued as rs779963815, COSV100698760; called by muse, mutect2, varscan2
- CIART | c.200G>C p.R67P | Missense Mutation (SNP) | VAF 155/380 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV51746083; called by muse, mutect2, varscan2
- CLDN22 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1279495228; called by muse, mutect2, varscan2
- CLEC18B | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 120/1443 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs771270666; called by muse, mutect2
- CNTNAP5 | c.3824A>T p.K1275M | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70480830; called by muse, mutect2, varscan2
- COL11A1 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770689108; called by muse, mutect2, varscan2
- DCX | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 159/200 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM131049, COSV57566118; called by muse, mutect2, varscan2
- DGKZ | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 123/683 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.729); catalogued as rs1565000485; called by muse, mutect2, varscan2
- DUSP19 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 21/150 reads (14%) | catalogued as rs1371503840, COSV100700283; called by muse, mutect2, varscan2
- EHD3 | c.1593G>T p.R531S | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100434921; called by muse, mutect2, varscan2
- EIF2A | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs780585569; called by muse, mutect2, varscan2
- FANCM | c.3436G>A p.D1146N | Missense Mutation (SNP) | VAF 122/312 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.413); catalogued as rs142077813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAR2 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs999660619; called by muse, mutect2, varscan2
- HCN1 | c.2495G>A p.R832K | Missense Mutation (SNP) | VAF 249/371 reads (67%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs199887416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIGD2B | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 271/438 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs781242221, COSV100304499; called by muse, mutect2, varscan2
- IGLON5 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 113/172 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421408817; called by muse, mutect2, varscan2
- KDM4D | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 162/426 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs782495913, COSV58634822; called by muse, mutect2, varscan2
- LRP8 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 191/575 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs372461064; called by muse, mutect2, varscan2
- LRRN4CL | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 302/766 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54015044; called by muse, mutect2, varscan2
- MAB21L1 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 169/375 reads (45%) | catalogued as COSV100076182; called by muse, mutect2, varscan2
- MAGEB6 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 140/205 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV66871893, COSV66872236; called by muse, mutect2, varscan2
- MAGI3 | c.3114del p.K1039Rfs*61 | Frame Shift Del (DEL) | VAF 70/201 reads (35%) | catalogued as rs1291819387; called by mutect2, pindel, varscan2
- MAN1B1 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 186/495 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65371855; called by muse, mutect2, varscan2
- MEX3B | c.258T>C p.G86= | Splice Region (SNP) | VAF 198/297 reads (67%) | catalogued as COSV61663088; called by muse, mutect2, varscan2
- MKI67 | c.4657G>T p.A1553S | Missense Mutation (SNP) | VAF 382/508 reads (75%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.7); catalogued as COSV64076538; called by muse, mutect2, varscan2
- MME | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 92/435 reads (21%) | catalogued as COSV100852487, COSV64709353, COSV64709653; called by muse, mutect2, varscan2
- MRPL3 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 91/131 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as rs1464788559; called by muse, mutect2, varscan2
- MS4A3 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV99614902; called by muse, mutect2, varscan2
- MUC16 | c.3404C>T p.A1135V | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1466194175; called by muse, mutect2, varscan2
- NBPF10 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 419/711 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs1553794527; called by muse, varscan2
- NOC2L | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 121/455 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs779499305; called by muse, mutect2, varscan2
- NOS1 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV57606647; called by muse, mutect2, varscan2
- OR1S1 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 137/380 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs751706356; called by muse, mutect2, varscan2
- OR51I1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66508569; called by muse, mutect2, varscan2
- OR5AP2 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57257536; called by muse, mutect2, varscan2
- OR6B1 | c.249T>A p.F83L | Missense Mutation (SNP) | VAF 86/129 reads (67%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101281658; called by muse, mutect2, varscan2
- OR6M1 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as COSV58432789; called by muse, mutect2, varscan2
- PCDH10 | c.1399G>C p.V467L | Missense Mutation (SNP) | VAF 139/332 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV52094262; called by muse, mutect2, varscan2
- PDE3A | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1270714595; called by mutect2, varscan2
- PDE4B | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as rs763416674; called by muse, mutect2, varscan2
- PEX5L | c.1526C>A p.S509* | Nonsense Mutation (SNP) | VAF 35/324 reads (11%) | catalogued as rs990179349; called by muse, mutect2, varscan2
- PPP3R2 | c.116G>C p.S39T | Missense Mutation (SNP) | VAF 149/452 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs760800259; called by muse, mutect2, varscan2
- PROS1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 142/671 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs747259055, CM142190, COSV67776384; called by muse, mutect2, varscan2
- RIMS2 | c.1411C>T p.R471W (on ENST00000666250 / NM_001348490.2; = p.R279W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/677 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566248680, COSV51698013; called by muse, mutect2, varscan2
- SCN1A | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 208/401 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100319912; called by muse, mutect2, varscan2
- SKAP1 | c.974G>C p.S325T | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100411471; called by muse, mutect2, varscan2
- SLC11A2 | c.503G>A p.R168H (on ENST00000394904 / NM_001379455.1; = p.R139H on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/544 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs368158015; called by muse, varscan2
- SLC12A2 | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779677826; called by muse, mutect2, varscan2
- SLC30A3 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 68/525 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178344301; called by muse, mutect2, varscan2
- SLIT3 | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 301/421 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1038593723; called by muse, mutect2, varscan2
- SMAD6 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 174/283 reads (61%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56597518; called by muse, mutect2, varscan2
- TBX22 | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 191/238 reads (80%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs1440442525, COSV64785520; called by muse, mutect2, varscan2
- TEX43 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs765190069; called by muse, mutect2, varscan2
- TIMD4 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 119/154 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs141557472, COSV50855913; called by muse, mutect2, varscan2
- TRIM49C | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs532468553, COSV101442238; called by muse, mutect2, varscan2
- TRIM50 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 522/1298 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV52722924; called by muse, mutect2, varscan2
- TSHZ3 | c.2759G>A p.G920E | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53674652; called by muse, mutect2, varscan2
- TSNARE1 | c.1481C>G p.S494* | Nonsense Mutation (SNP) | VAF 154/738 reads (21%) | catalogued as COSV56176928; called by muse, varscan2
- TTC33 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs144481517, COSV61802990; called by muse, mutect2, varscan2
- TTN | c.16351G>A p.D5451N (on ENST00000591111; = p.D4524N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/158 reads (24%) | PolyPhen benign (0.052); catalogued as rs576904726, COSV59905599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.3058G>C p.E1020Q (on ENST00000591111; = p.E974Q on NM_003319.4) | Missense Mutation (SNP) | VAF 77/349 reads (22%) | PolyPhen benign (0.028); catalogued as COSV60245206; called by muse, mutect2, varscan2
- USP17L2 | c.411C>G p.H137Q | Missense Mutation (SNP) | VAF 468/617 reads (76%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs780196046, COSV61556052; called by muse, mutect2, varscan2
- USP48 | c.248G>C p.R83T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57614861; called by muse, mutect2, varscan2
- VPS50 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52497446; called by muse, mutect2, varscan2
- WDR72 | c.3213C>G p.D1071E | Missense Mutation (SNP) | VAF 238/376 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.194); catalogued as COSV64741104; called by muse, varscan2
- XAGE2 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 104/127 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV53684676; called by muse, mutect2, varscan2
- ZFR2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 120/351 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53596360; called by muse, mutect2, varscan2
- ZFYVE26 | c.5504G>A p.C1835Y | Missense Mutation (SNP) | VAF 150/472 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100720224; called by muse, mutect2, varscan2
- ZNF140 | c.1000T>C p.C334R | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300040526; called by muse, mutect2, varscan2
- ZNF335 | c.3188G>T p.R1063L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs777626902, COSV100532879; called by muse, mutect2, varscan2
- ZNF407 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs777198607; called by muse, mutect2, varscan2
- ZNF714 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs773438254; called by muse, mutect2, varscan2
- ZNF99 | c.1736A>T p.H579L | Missense Mutation (SNP) | VAF 122/370 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as rs1489413069; called by muse, mutect2, varscan2
- ABCA5 | c.2452G>T p.E818* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- AL713998.4 | n.131T>A | Splice Region (SNP) | VAF 80/149 reads (54%) | called by muse, mutect2, varscan2
- ANKH | c.1367A>T p.K456I | Missense Mutation (SNP) | VAF 440/617 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- APOB | c.11005C>A p.L3669I | Missense Mutation (SNP) | VAF 120/191 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ARHGAP39 | c.1848C>G p.H616Q | Missense Mutation (SNP) | VAF 193/1098 reads (18%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ARID1A | c.6324del p.N2109Mfs*26 | Frame Shift Del (DEL) | VAF 135/388 reads (35%) | called by mutect2, pindel, varscan2
- BCAS3 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BCHE | c.1393A>T p.M465L | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BRAT1 | c.1493T>A p.L498H | Missense Mutation (SNP) | VAF 121/319 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- C1QL2 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C2orf49 | c.607A>C p.K203Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1E | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCDC63 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCS | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CD70 | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 268/643 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CELSR2 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 358/863 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CHEK1 | c.610G>T p.G204* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- CLEC4M | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 291/890 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CLSPN | c.1033A>G p.K345E | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CNGB3 | c.1642G>C p.G548R | Missense Mutation (SNP) | VAF 182/485 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL11A1 | c.626G>T p.R209M | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- COL8A1 | c.2037C>A p.F679L | Missense Mutation (SNP) | VAF 73/576 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CPEB2 | c.2177-1G>T p.X726_splice | Splice Site (SNP) | VAF 10/17 reads (59%) | called by muse, varscan2
- CPLANE1 | c.8576A>T p.D2859V | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CSF2RA | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 79/458 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CST9L | c.209T>G p.L70R | Missense Mutation (SNP) | VAF 114/322 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- CTNND2 | c.3182C>T p.P1061L | Missense Mutation (SNP) | VAF 973/1455 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CTNND2 | c.1360C>A p.R454S | Missense Mutation (SNP) | VAF 330/480 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CUBN | c.2935C>A p.L979M | Missense Mutation (SNP) | VAF 172/225 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYBC1 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2
- CYBC1 | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- CYP4A22 | c.1047G>T p.E349D | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- DCHS1 | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 124/362 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2
- DCLRE1C | c.779A>C p.K260T (on ENST00000378278 / NM_001350965.2; = p.K145T on NM_022487.4) | Missense Mutation (SNP) | VAF 486/612 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DEPDC1B | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 47/65 reads (72%) | called by muse, mutect2
- DMD | c.3824del p.L1275Wfs*8 | Frame Shift Del (DEL) | VAF 67/108 reads (62%) | called by mutect2, pindel, varscan2
- DMD | c.1681T>A p.W561R | Missense Mutation (SNP) | VAF 136/176 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.2488G>T p.D830Y | Missense Mutation (SNP) | VAF 125/218 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DRAXIN | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 164/425 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DSCAML1 | c.3317G>C p.G1106A (on ENST00000321322; = p.G1046A on NM_020693.4) | Missense Mutation (SNP) | VAF 200/600 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- E2F7 | c.339C>G p.N113K | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- E2F8 | c.1894-1G>C p.X632_splice | Splice Site (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- ELMOD1 | c.895T>C p.F299L | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXT1 | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 92/1084 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.516); called by muse, mutect2
- FAM135B | c.3431dup p.C1144Wfs*34 | Frame Shift Ins (INS) | VAF 95/534 reads (18%) | called by mutect2, pindel, varscan2
- FBXL7 | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 304/2065 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- FCRL4 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- FN1 | c.3896T>C p.L1299P | Missense Mutation (SNP) | VAF 75/419 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FN1 | c.1839A>C p.E613D | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FRG2 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 192/406 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- FSCN1 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 191/519 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSD1L | c.1448del p.P483Qfs*15 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- GAB2 | c.1010A>G p.N337S (on ENST00000361507 / NM_080491.3; = p.N299S on NM_012296.3) | Missense Mutation (SNP) | VAF 292/736 reads (40%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GCOM1 | c.1079T>C p.V360A | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GK5 | c.1035G>T p.W345C | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GK5 | c.1034G>A p.W345* | Nonsense Mutation (SNP) | VAF 61/237 reads (26%) | called by muse, varscan2
- GRIA2 | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GRM3 | c.1934G>T p.R645L | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCLS1 | c.560A>T p.Q187L | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HFM1 | c.561C>A p.H187Q | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HHLA2 | c.125_127delinsAA p.R42Kfs*6 | Frame Shift Del (DEL) | VAF 32/206 reads (16%) | called by pindel, varscan2*
- HMGB1 | c.437del p.K146Rfs*6 | Frame Shift Del (DEL) | VAF 109/458 reads (24%) | called by mutect2, pindel, varscan2
- HNRNPCL1 | c.581T>A p.V194E | Missense Mutation (SNP) | VAF 175/476 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HRH2 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 75/476 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDH3A | c.371T>A p.V124D | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGFALS | c.1545C>A p.N515K | Missense Mutation (SNP) | VAF 291/803 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); called by mutect2, varscan2
- IGHV4-31 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 208/662 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- INTS9 | c.1002C>A p.N334K | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2
- ITGB2 | c.2041G>C p.V681L (on ENST00000302347; = p.V657L on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 382/644 reads (59%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITSN1 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KMT2D | c.16522-2A>C p.X5508_splice | Splice Site (SNP) | VAF 81/235 reads (34%) | called by muse, mutect2, varscan2
- LAMA1 | c.9189C>G p.H3063Q | Missense Mutation (SNP) | VAF 205/576 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA1 | c.470C>G p.S157* | Nonsense Mutation (SNP) | VAF 188/543 reads (35%) | called by mutect2, varscan2
- LCP2 | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LGSN | c.1226T>A p.L409Q | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMBRD1 | c.434T>C p.L145S | Missense Mutation (SNP) | VAF 128/269 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- LRRC7 | c.4569G>C p.Q1523H (on ENST00000651989 / NM_001370785.2; = p.Q1443H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRK2 | c.2310T>A p.D770E | Missense Mutation (SNP) | VAF 100/249 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LVRN | c.341A>C p.Q114P | Missense Mutation (SNP) | VAF 284/367 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by mutect2, varscan2
- MAD2L1 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MFN2 | c.2092C>T p.H698Y | Missense Mutation (SNP) | VAF 323/930 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MPL | c.1046T>C p.F349S | Missense Mutation (SNP) | VAF 175/499 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYLK | c.3559G>T p.V1187L | Missense Mutation (SNP) | VAF 176/1310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYT1L | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 102/596 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NALCN | c.3642G>T p.R1214S | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- NCAPH | c.2099del p.P700Lfs*19 | Frame Shift Del (DEL) | VAF 110/283 reads (39%) | called by mutect2, pindel, varscan2
- NEURL4 | c.2650G>T p.A884S | Missense Mutation (SNP) | VAF 149/250 reads (60%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR2E1 | c.524T>A p.M175K | Missense Mutation (SNP) | VAF 104/524 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NT5DC4 | c.681C>T p.A227= | Splice Region (SNP) | VAF 151/317 reads (48%) | called by muse, mutect2, varscan2
- OR10D3 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 124/255 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M4 | c.555A>T p.L185F | Missense Mutation (SNP) | VAF 171/220 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- OR4S1 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- OR5R1 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 116/264 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR6B1 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 88/128 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- OR8H3 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OTUD6B | c.791T>A p.I264K | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PAPLN | c.3721C>A p.L1241M (on ENST00000554301; = p.L1214M on NM_173462.4) | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA4 | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 294/409 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDILT | c.1403G>T p.S468I | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.035); called by muse, mutect2
- PEG10 | c.594C>A p.N198K (on ENST00000482108 / NM_001040152.2; = p.N232K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 1053/1398 reads (75%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PEG3 | c.1747A>T p.K583* | Nonsense Mutation (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- PGK2 | c.665A>G p.Q222R | Missense Mutation (SNP) | VAF 142/213 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PIWIL1 | c.2264G>T p.R755I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- PLEKHH3 | c.285_289del p.I96Cfs*64 | Frame Shift Del (DEL) | VAF 188/398 reads (47%) | called by mutect2, pindel, varscan2
- PLG | c.2226del p.E743Nfs*64 | Frame Shift Del (DEL) | VAF 57/357 reads (16%) | called by mutect2, pindel, varscan2
- POM121 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 437/1091 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- POMGNT2 | c.17T>A p.V6E | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PPP1R16A | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 58/728 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRAMEF6 | c.616T>A p.C206S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- PRDM10 | c.3425T>A p.I1142N | Missense Mutation (SNP) | VAF 158/417 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM16 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCZ | c.887G>C p.W296S | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTH2R | c.1035G>T p.W345C | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRD | c.5450G>A p.G1817E | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB6C | c.178G>T p.G60* | Nonsense Mutation (SNP) | VAF 36/221 reads (16%) | called by muse, mutect2, varscan2
- RABEP1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RFX5 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 362/926 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RGL1 | c.59C>A p.T20N | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RNF185 | c.95G>C p.G32A | Missense Mutation (SNP) | VAF 115/455 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF40 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 205/550 reads (37%) | called by muse, mutect2, varscan2
- RTTN | c.6595del p.T2199Lfs*6 (on ENST00000255674; = p.T2199Lfs*10 on NM_173630.4) | Frame Shift Del (DEL) | VAF 38/127 reads (30%) | called by mutect2, pindel, varscan2
- SEMA4D | c.1078G>T p.G360C | Missense Mutation (SNP) | VAF 186/496 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A18 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 122/222 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SLC37A2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 130/366 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC46A2 | c.1035T>A p.F345L | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC4A11 | c.925A>C p.S309R | Missense Mutation (SNP) | VAF 363/930 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLITRK4 | c.1072A>T p.S358C | Missense Mutation (SNP) | VAF 76/99 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SOX1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 149/218 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPANXN2 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 68/80 reads (85%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.752); called by muse, varscan2
- SPATA31D1 | c.140T>A p.L47* | Nonsense Mutation (SNP) | VAF 102/252 reads (40%) | called by muse, mutect2, varscan2
- SPIC | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- SPIC | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPTA1 | c.4400C>A p.A1467D | Missense Mutation (SNP) | VAF 220/519 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- STAB2 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAOK3 | c.1308del p.T437Rfs*39 | Frame Shift Del (DEL) | VAF 138/389 reads (35%) | called by mutect2, pindel, varscan2
- TBC1D4 | c.1735G>C p.A579P | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- TEX15 | c.424A>G p.K142E (on ENST00000256246; = p.K525E on NM_001350162.2) | Missense Mutation (SNP) | VAF 73/121 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TGOLN2 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 393/617 reads (64%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TLE5 | c.48G>C p.Q16H | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNFRSF10D | c.1130A>T p.D377V | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- TNN | c.2130C>A p.S710R | Missense Mutation (SNP) | VAF 242/799 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, varscan2
- TNN | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 245/810 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- TPI1 | c.855A>C p.K285N (on ENST00000229270; = p.K248N on NM_000365.6) | Missense Mutation (SNP) | VAF 310/823 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRAV22 | c.174C>G p.N58K | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TRIM50 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 288/995 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM50 | c.267C>A p.C89* | Nonsense Mutation (SNP) | VAF 522/1289 reads (40%) | called by muse, mutect2, varscan2
- TRPM3 | c.3286A>T p.I1096F (on ENST00000357533 / NM_001366142.2; = p.I951F on NM_020952.6) | Missense Mutation (SNP) | VAF 213/570 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- TTN | c.78226A>T p.T26076S (on ENST00000591111; = p.T18652S on NM_003319.4) | Missense Mutation (SNP) | VAF 63/207 reads (30%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.57751G>C p.G19251R (on ENST00000591111; = p.G11827R on NM_003319.4) | Missense Mutation (SNP) | VAF 185/393 reads (47%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBA1B | c.1347G>C p.E449D | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.217); called by muse, mutect2
- UBOX5 | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBQLNL | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- UNCX | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- USH1C | c.1157T>G p.L386W | Missense Mutation (SNP) | VAF 224/628 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- VPS35L | c.1714T>C p.F572L | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VPS41 | c.1738-1G>A p.X580_splice | Splice Site (SNP) | VAF 72/185 reads (39%) | called by muse, mutect2, varscan2
- WDFY1 | c.206-1G>T p.X69_splice | Splice Site (SNP) | VAF 39/64 reads (61%) | called by muse, mutect2, varscan2
- WDR17 | c.1911G>A p.W637* | Nonsense Mutation (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
- WDR17 | c.1912G>T p.D638Y | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3HC1 | c.683dup p.T229Nfs*2 | Frame Shift Ins (INS) | VAF 55/101 reads (54%) | called by mutect2, pindel, varscan2
- ZNF467 | c.1537C>A p.R513S | Missense Mutation (SNP) | VAF 130/230 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZNF835 | c.646C>A p.H216N | Missense Mutation (SNP) | VAF 229/624 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF836 | c.1595G>C p.G532A | Missense Mutation (SNP) | VAF 93/148 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCA8 | c.3624A>G p.P1208= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs761674018; called by muse, mutect2, varscan2
- ADGRB3 | c.693C>A p.T231= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as COSV65403550; called by muse, mutect2, varscan2
- AFF3 | c.585C>A p.T195= | Silent (SNP) | VAF 114/263 reads (43%) | catalogued as COSV57856352; called by muse, mutect2, varscan2
- ASPN | c.814C>T p.L272= | Silent (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- ASTN2 | c.1245G>A p.T415= (on ENST00000313400 / NM_001365069.1; = p.T364= on NM_014010.5) | Silent (SNP) | VAF 115/346 reads (33%) | catalogued as rs776094932, COSV100531139; called by muse, mutect2, varscan2
- B3GALT6 | c.639G>A p.A213= | Silent (SNP) | VAF 113/279 reads (41%) | called by muse, mutect2, varscan2
- BAIAP3 | c.2607C>A p.G869= | Silent (SNP) | VAF 109/344 reads (32%) | catalogued as COSV50103781; called by muse, mutect2, varscan2
- BCHE | c.1392G>C p.V464= | Silent (SNP) | VAF 95/394 reads (24%) | catalogued as COSV100012199; called by muse, mutect2, varscan2
- C10orf71 | c.3951G>C p.G1317= | Silent (SNP) | VAF 267/331 reads (81%) | called by muse, mutect2, varscan2
- CD40 | c.9T>C p.R3= | Silent (SNP) | VAF 398/1014 reads (39%) | catalogued as rs1336243656; called by muse, mutect2, varscan2
- CDKL2 | c.1434G>C p.L478= | Silent (SNP) | VAF 62/94 reads (66%) | called by muse, mutect2, varscan2
- CDO1 | c.294A>G p.L98= | Silent (SNP) | VAF 124/168 reads (74%) | called by muse, mutect2, varscan2
- CDPF1 | c.69G>T p.P23= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs777668682; called by muse, mutect2, varscan2
- CHRND | c.1302G>A p.E434= | Silent (SNP) | VAF 400/736 reads (54%) | called by muse, mutect2, varscan2
- CIITA | c.649T>C p.L217= | Silent (SNP) | VAF 336/864 reads (39%) | catalogued as rs773897183, COSV60861354; called by muse, mutect2, varscan2
- CMKLR1 | c.1050T>C p.H350= (on ENST00000312143 / NM_001142344.2; = p.H348= on NM_004072.3) | Silent (SNP) | VAF 88/233 reads (38%) | called by muse, mutect2, varscan2
- CNTN1 | c.2415A>G p.Q805= | Silent (SNP) | VAF 97/302 reads (32%) | catalogued as rs1015613979; called by muse, mutect2, varscan2
- CNTN5 | c.3105C>A p.L1035= | Silent (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- CRACR2B | c.1194C>T p.A398= | Silent (SNP) | VAF 128/385 reads (33%) | called by muse, mutect2, varscan2
- CSMD2 | c.3042C>A p.V1014= | Silent (SNP) | VAF 228/686 reads (33%) | called by muse, mutect2, varscan2
- CSMD3 | c.9363C>A p.A3121= (on ENST00000297405 / NM_001363185.1; = p.A2952= on NM_052900.3) | Silent (SNP) | VAF 161/442 reads (36%) | called by muse, mutect2, varscan2
- CST9L | c.210G>T p.L70= | Silent (SNP) | VAF 112/311 reads (36%) | called by mutect2, varscan2
- DCHS1 | c.1278G>T p.V426= | Silent (SNP) | VAF 122/366 reads (33%) | called by muse, mutect2
- DCSTAMP | c.927G>A p.L309= | Silent (SNP) | VAF 140/643 reads (22%) | called by muse, mutect2, varscan2
- DNAH3 | c.9414C>A p.I3138= | Silent (SNP) | VAF 93/228 reads (41%) | called by muse, mutect2, varscan2
- EGF | c.2847G>C p.L949= | Silent (SNP) | VAF 104/235 reads (44%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.2316G>T p.A772= | Silent (SNP) | VAF 45/133 reads (34%) | called by muse, mutect2, varscan2
- ELFN1 | c.1371C>T p.A457= | Silent (SNP) | VAF 96/245 reads (39%) | catalogued as rs761197449; called by muse, mutect2, varscan2
- FLACC1 | c.1305G>A p.V435= | Silent (SNP) | VAF 43/196 reads (22%) | called by muse, mutect2, varscan2
- FOXD4L3 | c.123C>T p.D41= | Silent (SNP) | VAF 153/1159 reads (13%) | catalogued as COSV61551166; called by muse, mutect2, varscan2
- GCKR | c.996G>C p.L332= | Silent (SNP) | VAF 592/914 reads (65%) | called by muse, varscan2
- GCKR | c.1035T>C p.D345= | Silent (SNP) | VAF 282/936 reads (30%) | catalogued as COSV53108725; called by muse, varscan2
- GLG1 | c.894G>T p.V298= | Silent (SNP) | VAF 106/286 reads (37%) | called by mutect2, varscan2
- GP2 | c.849C>A p.A283= (on ENST00000381362 / NM_001007240.3; = p.A280= on NM_001502.4) | Silent (SNP) | VAF 152/420 reads (36%) | catalogued as rs1299036460; called by muse, mutect2, varscan2
- HEATR5A | c.555C>T p.C185= | Silent (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- HPDL | c.48C>T p.P16= | Silent (SNP) | VAF 82/201 reads (41%) | catalogued as rs773729138; called by muse, mutect2, varscan2
- ITPR2 | c.7053G>A p.A2351= | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as rs770297282, COSV67276139; called by muse, mutect2, varscan2
- KIAA1328 | c.1611G>T p.G537= | Silent (SNP) | VAF 212/661 reads (32%) | called by muse, varscan2
- LARGE1 | c.1953T>G p.V651= | Silent (SNP) | VAF 162/528 reads (31%) | called by muse, mutect2, varscan2
- LIPG | c.330C>T p.H110= | Silent (SNP) | VAF 176/509 reads (35%) | called by muse, mutect2, varscan2
- MCF2 | c.2757G>T p.S919= | Silent (SNP) | VAF 44/56 reads (79%) | called by muse, mutect2, varscan2
- MSH4 | c.1605A>T p.R535= | Silent (SNP) | VAF 58/194 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.34065A>G p.A11355= | Silent (SNP) | VAF 129/374 reads (34%) | called by muse, mutect2, varscan2
- MUC7 | c.702C>T p.T234= | Silent (SNP) | VAF 294/564 reads (52%) | called by muse, varscan2
- MYO16 | c.798C>A p.G266= | Silent (SNP) | VAF 65/107 reads (61%) | called by muse, mutect2, varscan2
- OR4A15 | c.834C>A p.P278= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as rs765105268; called by muse, mutect2, varscan2
- OR52K2 | c.180C>T p.P60= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as rs1444263083; called by muse, mutect2
- OR5F1 | c.321G>T p.L107= | Silent (SNP) | VAF 89/220 reads (40%) | called by muse, mutect2, varscan2
- PALLD | c.1353C>A p.A451= | Silent (SNP) | VAF 127/594 reads (21%) | called by muse, mutect2, varscan2
- PBX3 | c.69G>T p.G23= | Silent (SNP) | VAF 152/392 reads (39%) | catalogued as rs1189164240; called by muse, mutect2, varscan2
- PCDH17 | c.1101C>A p.P367= | Silent (SNP) | VAF 246/436 reads (56%) | catalogued as rs539470525; called by muse, mutect2, varscan2
- PHETA1 | c.138C>G p.L46= | Silent (SNP) | VAF 125/358 reads (35%) | called by muse, mutect2, varscan2
- PHEX | c.708T>G p.L236= | Silent (SNP) | VAF 169/220 reads (77%) | called by muse, mutect2, varscan2
- PHKA2 | c.702G>A p.E234= | Silent (SNP) | VAF 218/300 reads (73%) | called by muse, mutect2, varscan2
- PLXNC1 | c.1029C>T p.V343= | Silent (SNP) | VAF 78/291 reads (27%) | called by muse, mutect2, varscan2
- PUM1 | c.2229C>T p.P743= | Silent (SNP) | VAF 87/624 reads (14%) | catalogued as rs150169072; called by muse, mutect2, varscan2
- RBMXL3 | c.1677G>T p.S559= | Silent (SNP) | VAF 260/344 reads (76%) | called by muse, mutect2, varscan2
- RPL28 | c.135C>T p.H45= | Silent (SNP) | VAF 100/164 reads (61%) | catalogued as rs1372000824; called by muse, mutect2, varscan2
- SEC14L6 | c.654G>C p.V218= | Silent (SNP) | VAF 79/323 reads (24%) | called by muse, mutect2, varscan2
- SHD | c.288C>A p.P96= | Silent (SNP) | VAF 99/234 reads (42%) | called by muse, mutect2, varscan2
- SLC5A1 | c.654G>C p.L218= | Silent (SNP) | VAF 15/223 reads (7%) | catalogued as rs199689867; called by muse, mutect2
- SLIT2 | c.1371C>T p.C457= | Silent (SNP) | VAF 14/307 reads (5%) | called by muse, mutect2
- SON | c.4767A>T p.A1589= | Silent (SNP) | VAF 87/127 reads (69%) | called by muse, mutect2, varscan2
- SPHKAP | c.390C>T p.V130= | Silent (SNP) | VAF 81/162 reads (50%) | catalogued as rs113031300; called by muse, mutect2, varscan2
- STAB2 | c.1566A>G p.T522= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV66348451; called by muse, mutect2, varscan2
- SUPT20H | c.678G>A p.K226= (on ENST00000350612 / NM_001014286.3; = p.K227= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/214 reads (45%) | called by muse, mutect2, varscan2
- TAF1A | c.684A>C p.A228= | Silent (SNP) | VAF 103/143 reads (72%) | called by muse, mutect2, varscan2
- TAS1R1 | c.612G>A p.Q204= | Silent (SNP) | VAF 17/551 reads (3%) | called by muse, mutect2
- TMEM72 | c.330C>A p.V110= | Silent (SNP) | VAF 78/332 reads (23%) | catalogued as COSV101273547; called by muse, mutect2, varscan2
- TSHZ3 | c.2496A>T p.S832= | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- TSPAN11 | c.693C>A p.A231= | Silent (SNP) | VAF 118/288 reads (41%) | catalogued as COSV53819430; called by muse, mutect2, varscan2
- TTLL9 | c.372G>T p.L124= | Silent (SNP) | VAF 162/410 reads (40%) | called by muse, mutect2, varscan2
- UPF2 | c.3711G>A p.Q1237= | Silent (SNP) | VAF 56/412 reads (14%) | called by muse, mutect2, varscan2
- USH2A | c.5835T>C p.S1945= | Silent (SNP) | VAF 315/403 reads (78%) | called by muse, mutect2, varscan2
- USP34 | c.3027G>A p.E1009= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- VWF | c.5910C>T p.G1970= | Silent (SNP) | VAF 240/540 reads (44%) | catalogued as COSV54623985; called by muse, mutect2, varscan2
- ZNF468 | c.978A>T p.P326= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV54693530; called by muse, mutect2
- AC098591.2 | n.1105A>G | RNA (SNP) | VAF 254/421 reads (60%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.130-33992G>T | Intron (SNP) | VAF 90/162 reads (56%) | called by muse, mutect2, varscan2
- CABYR | c.*17-137G>T | Intron (SNP) | VAF 141/431 reads (33%) | called by muse, mutect2, varscan2
- CCM2 | c.473-34A>G | Intron (SNP) | VAF 207/518 reads (40%) | called by muse, mutect2, varscan2
- CLEC4A | c.299-1213C>T | Intron (SNP) | VAF 249/647 reads (38%) | called by muse, mutect2, varscan2
- COL4A2 | c.648+207G>T | Intron (SNP) | VAF 138/250 reads (55%) | called by muse, mutect2, varscan2
- DPP9 | c.2245-175C>T | Intron (SNP) | VAF 50/374 reads (13%) | catalogued as rs1294095367; called by muse, varscan2
- FAM131A | chr3:184338460 T>A | 5'Flank (SNP) | VAF 232/403 reads (58%) | called by muse, mutect2, varscan2
- FAM182B | n.797G>T | RNA (SNP) | VAF 73/434 reads (17%) | catalogued as COSV64518226; called by muse, varscan2
- FAM20A | c.*2170A>G | 3'UTR (SNP) | VAF 305/365 reads (84%) | catalogued as rs759651825; called by muse, mutect2, varscan2
- FRMD3 | c.1196-18537G>A | Intron (SNP) | VAF 73/186 reads (39%) | catalogued as rs747092578; called by muse, mutect2, varscan2
- GLTPP1 | n.45C>A | RNA (SNP) | VAF 377/1081 reads (35%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+116G>A | Intron (SNP) | VAF 58/1188 reads (5%) | called by muse, mutect2
- JAZF1 | c.115+18G>T | Intron (SNP) | VAF 266/663 reads (40%) | called by muse, mutect2, varscan2
- LINC00923 | n.83T>C | RNA (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- LPL | c.250-45A>G | Intron (SNP) | VAF 123/193 reads (64%) | called by muse, mutect2, varscan2
- LTO1 | c.50+134C>G | Intron (SNP) | VAF 29/195 reads (15%) | catalogued as rs758140386; called by muse, mutect2, varscan2
- NMRK2 | c.-24T>C | 5'UTR (SNP) | VAF 98/307 reads (32%) | called by muse, mutect2, varscan2
- OR7D1P | n.525G>A | RNA (SNP) | VAF 147/451 reads (33%) | catalogued as rs539111941; called by muse, mutect2, varscan2
- OXLD1 | c.60+192C>A | Intron (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- PIEZO1 | c.161-936G>T | Intron (SNP) | VAF 64/166 reads (39%) | called by muse, mutect2, varscan2
- POM121 | chr7:72949928 G>A | 3'Flank (SNP) | VAF 24/706 reads (3%) | catalogued as rs782732943; called by muse, mutect2
- PYY3 | n.133C>A | RNA (SNP) | VAF 285/355 reads (80%) | called by muse, mutect2, varscan2
- RAB40B | c.-90G>C | 5'UTR (SNP) | VAF 21/90 reads (23%) | catalogued as rs1280097982; called by muse, mutect2, varscan2
- RAD21 | chr8:116874850 A>G | 5'Flank (SNP) | VAF 235/1123 reads (21%) | called by muse, mutect2, varscan2
- SERPINA3 | c.644-51C>A | Intron (SNP) | VAF 182/432 reads (42%) | called by mutect2, varscan2
- SHFL | c.196-352A>T | Intron (SNP) | VAF 209/646 reads (32%) | called by muse, mutect2, varscan2
- SLC35C2 | c.-118C>T | 5'UTR (SNP) | VAF 249/677 reads (37%) | catalogued as rs566339438; called by muse, mutect2, varscan2
- SLC9B1P1 | n.485C>A | RNA (SNP) | VAF 29/266 reads (11%) | called by muse, mutect2, varscan2
- SNORD115-26 | n.49A>T | RNA (SNP) | VAF 194/346 reads (56%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.842G>A | RNA (SNP) | VAF 143/1055 reads (14%) | catalogued as rs644084; called by muse, mutect2, varscan2
- STAG3 | c.*20C>G | 3'UTR (SNP) | VAF 24/476 reads (5%) | catalogued as rs931505933; called by muse, mutect2
- TNC | c.4580-4235A>G | Intron (SNP) | VAF 90/246 reads (37%) | catalogued as rs746435421; called by muse, mutect2
- TPO | c.*87C>A | 3'UTR (SNP) | VAF 47/338 reads (14%) | called by muse, mutect2, varscan2
- TRIML2 | c.621+826C>G | Intron (SNP) | VAF 19/59 reads (32%) | catalogued as rs1213985722; called by muse, mutect2, varscan2
- VGF | c.*6C>G | 3'UTR (SNP) | VAF 250/408 reads (61%) | called by muse, mutect2, varscan2
- ZNF208 | c.226+37G>T | Intron (SNP) | VAF 45/111 reads (41%) | catalogued as COSV101237275; called by muse, mutect2, varscan2
- ZNF720 | c.361+1294T>A | Intron (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
